Gene-level copy-number profile of tumor specimen TCGA-13-0916-01A from TCGA case TCGA-13-0916, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.8 years (18,189 days).
Specimen TCGA-13-0916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.75cbdc12-abdd-44a0-ac21-0ad30e6c5628.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0916-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebdbfa5f-8298-47db-adca-123108223104

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 25,913; copy number 2: 29,010; copy number 3: 3,354; copy number 4: 1,034; copy number 5: 419; copy number 6: 14; copy number 7: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0916-01A-01D-0399-01): tumor purity 0.91, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 507 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:123,041,968–145,066,685, 428 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:11,759,101–12,668,495, 16 genes, copy number 5: AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1.
- chr14:61,529,128–62,112,550, 12 genes, copy number 5 (within-gene range 3–5): AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1, AL137918.1, SYT16, COX4I1P1.
- chr14:64,704,102–65,335,183, 21 genes, copy number 5: PLEKHG3, SPTB, MIR7855, RPPH1-2P, CHURC1, CHURC1-FNTB, GPX2, RAB15, FNTB, AL139022.2, MAX, MIR4706, AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708.
- chr14:65,411,170–65,471,186, 3 genes, copy number 5: FUT8-AS1, RPL21P8, MIR625.
- chr18:77,249,848–79,378,287, 27 genes, copy number 5 (within-gene range 4–5): GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1.

Autosomal genes at a single copy (total copy number 1): 24,654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
